Somatic mutation profile of tumor specimen TARGET-40-NAAGJP-01A (aliquot TARGET-40-NAAGJP-01A-01D) from TARGET case TARGET-40-NAAGJP, project TARGET-OS (Osteosarcoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Osteosarcoma, NOS; Tissue or organ of origin: Long bones of lower limb and associated joints; Age at diagnosis: 30.0 years (10,941 days).
Specimen TARGET-40-NAAGJP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) dae432e0-6915-4591-ab37-dda08b5d7f08.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-40-NAAGJP-10A (Blood Derived Normal), aliquot TARGET-40-NAAGJP-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/650f4e08-563d-40c9-84e8-b79683578f35

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 3, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 26/125 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- LAMA2 | c.2735C>T p.A912V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as rs376580266, COSV101369833; called by muse, mutect2, varscan2
- PKD1L1 | c.2903A>G p.Q968R | Missense Mutation (SNP) | VAF 12/98 reads (12%) | SIFT tolerated (0.06); PolyPhen benign (0.066); catalogued as rs747422492; called by mutect2, varscan2
- MUC2 | chr11:1099183 C>T | 3'Flank (SNP) | VAF 22/198 reads (11%) | catalogued as rs796623549; called by muse, varscan2
